Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0TG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0TG-01A (Primary Tumor).

[page 1 of 3]
11

105-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium 054.1 And infertile 13

[page 2 of 3]
Surgical Pathology Report

Gross Description

- A. Received in formalin labeled "left aortic lymph node" consists of yellow tan portion of fibrofatty tissue weighing < 1 gram and measuring 2.3 x 1.0 x 0.4 cm. The entire specimen is submitted as cassette A.
- B. Received in formalin labeled "left pelvic lymph node" consists of yellow tan portion of fibrofatty tissue weighing in aggregate 6 grams and measuring in aggregate 4.0 x 3.5 x 2.0 cm. Several lymph nodes are identified measuring up to 6.0 cm in greatest dimensions. The entire specimen is submitted as follows:

KEY TO CASSETTES:

- B1-B2 - One lymph node, serially sectioned
B3 - Four lymph nodes
B4 - Remainder

- C. Received in formalin labeled "uterus, ovaries, tubes" consists of uterus and attached cervix with separately received adnexal structures weighing in aggregate 121 grams. The uterus is received partially bisected. The serosal surface is pink tan and smooth. The uterine corpus measures 8.5 x 6.5 x 4.5 cm. The cervix measures 3.5 cm in length and 3.8 cm in diameter. The endometrial surface is completely exocoelomic mucosa is pink-tan and smooth. A portion of vaginal cuff is attached. The endometrial surface is completely replaced by a fleshy polypoid mass. The mass appears to be located in the lower uterine segment. The mass measures an area of 5.0 x 4.3 cm. No obvious myometrial invasion is identified grossly. The thickness of tumor is 0.5 cm. The myometrial thickness is 1.2 cm. The adnexal structures are received separately. The right ovary measures 3.5 cm in length. A small piece has been removed. Cut surface is unremarkable. The fallopian tube measures 4.0 cm in length and 0.3 cm in diameter. There is evidence of previous ligation. The left ovary is tan measuring 2.7 cm in greatest dimension. A piece has been removed. Cut surface is unremarkable. The left ovary measures 6.5 cm in length and 0.8 cm in diameter. There is evidence of previous ligation. Representative sections are submitted as follows:

KEY TO CASSETTES:

- C1 - Cervix and vaginal cuff
C2-C3 - Lower uterine segment (vertical sections)
C4-C5 - Full thickness, endometrium
C6-C8 - Endometrium
C9 - Additional lower uterine segment
C10 - Parametrial tissue
C11 - Right adnexal structures
C12 - Left adnexal structures

- D. Received in formalin labeled "right pelvic lymph node" consists of multiple yellow tan portions of fibrofatty tissue weighing in aggregate 10 grams and measuring in aggregate 5.0 x 4.0 x 2.0 cm. Several lymph nodes are identified measuring up to 6.0 cm in greatest dimension. The entire specimen is submitted as follows:

KEY TO CASSETTES:

- D1-D2 - Single lymph node, serially sectioned
D3 - Single lymph node, bisected
D4 - Single lymph node
D5-D6 - Remainder

- E. Received in formalin labeled "right para-aortic lymph node" consists of two portions of yellow tan fibrofatty tissue weighing 2 grams in aggregate and measuring 2.0 x 2.0 x 1.2 cm. The entire specimen is submitted as follows:

KEY TO CASSETTES:

- E1 - Two lymph nodes
E2 - Remainder

Microscopic Description

The microscopic findings support the above diagnosis.

[page 3 of 3]
Surgical Pathology Report

Source: NCI Genomic Data Commons file 3309209b-f742-43c3-a476-f6e4d51d6c95 (TCGA-BS-A0TG.7A7B4B4B-5EE2-4D8D-A90A-DDFB96AE49A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).